Somatic mutation profile of tumor specimen TCGA-S9-A6TZ-01A (aliquot TCGA-S9-A6TZ-01A-21D-A32B-08) from TCGA case TCGA-S9-A6TZ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.0 years (14,592 days).
Specimen TCGA-S9-A6TZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72047962-400f-4c35-a37a-ce5fa76d7838.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6TZ-10A (Blood Derived Normal), aliquot TCGA-S9-A6TZ-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed8f087c-a6ef-4e90-aa77-b130c90cba1d

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 21, Silent 12, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs137852247, CM1314241, CM940587, COSV54378539; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP4B1 | c.1499A>T p.Y500F | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV99870668; called by muse, mutect2
- BRCA2 | c.4178C>T p.A1393V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs398122776, COSV66448197; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- CD72 | c.82+1G>T p.X28_splice | Splice Site (SNP) | VAF 30/69 reads (43%) | catalogued as COSV99427354; called by muse, mutect2, varscan2
- CTR9 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100797303; called by muse, mutect2, varscan2
- CUL4B | c.1586T>A p.I529K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100340295; called by muse, mutect2
- ESX1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV101006419; called by muse, mutect2
- HBS1L | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892531; called by muse, mutect2
- MAGEA11 | c.744G>C p.M248I | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV100290438; called by muse, mutect2
- MAMDC4 | c.2614A>G p.T872A (on ENST00000445819; = p.T793A on NM_206920.3) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV99807924; called by muse, mutect2
- NKD2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs199906392; called by muse, mutect2, varscan2
- NNT | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs749214927, COSV99238625; called by muse, mutect2, varscan2
- NT5C1B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.099); catalogued as rs368786487; called by muse, mutect2, varscan2
- PKHD1 | c.11348C>G p.P3783R | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100944107; called by muse, mutect2, varscan2
- RAP2C | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747304; called by muse, mutect2, varscan2
- SHROOM2 | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV101098382; called by muse, mutect2
- TCEA2 | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV100180653; called by muse, mutect2, varscan2
- TMEM104 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755546280, COSV100120593; called by muse, mutect2, varscan2
- ZP2 | c.1556T>C p.F519S | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99559331; called by muse, mutect2
- POLR2A | c.3794A>T p.D1265V | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TCF12 | c.624_627delinsAGG p.P209Gfs*36 | Frame Shift Del (DEL) | VAF 53/151 reads (35%) | called by pindel, varscan2*
- ADH1C | c.459G>C p.V153= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV101565173; called by muse, mutect2
- CASZ1 | c.2820C>T p.N940= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs141036792, COSV100681052; called by muse, mutect2, varscan2
- DCHS1 | c.4968C>T p.V1656= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs144759454; called by muse, mutect2, varscan2
- GPC6 | c.24G>T p.V8= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV100988299, COSV65502127; called by muse, mutect2, varscan2
- KCND2 | c.462C>T p.T154= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs1443815775, COSV58582307, COSV58582716; called by muse, mutect2
- KSR1 | c.2313G>A p.E771= (on ENST00000644974 / NM_001367810.1; = p.E656= on NM_014238.2) | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV52028516, COSV99258862; called by muse, mutect2, varscan2
- MRGPRD | c.859C>T p.L287= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100482919, COSV100482964; called by muse, mutect2, varscan2
- POMT2 | c.834C>T p.H278= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99836293; called by muse, mutect2, varscan2
- RCN3 | c.189A>G p.E63= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV99571242; called by muse, mutect2, varscan2
- RHOXF2B | c.372C>T p.A124= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV101003950; called by mutect2, varscan2
- TMPRSS11F | c.444G>A p.K148= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100678348; called by muse, mutect2, varscan2
- UGT2B7 | c.81G>T p.L27= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV100535145; called by muse, mutect2, varscan2
